Surgical pathology report (de-identified scan), TCGA case TCGA-EU-5904, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site CHI-Penrose Colorado, specimen TCGA-EU-5904-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

SPECIMEN

A. KIDNEY - 1. Right kidney

CLINICAL INFORMATION

Right renal mass

COPY TO: [REDACTED]

GROSS DESCRIPTION

Received in formalin labeled [REDACTED] right kidney" is a 201 gram, 12.2 x 6.9 x 4.8 cm kidney with scant attached perinephric fat. Approximately 70% of the kidney is covered by smooth tan-pink renal capsule. There are numerous white plastic clamps in the hilum; however, no definite ureter is identified. Sections of the vascular margins, as well as margins of the pelvis/calices present in the hilar surgical margin are submitted as (A1). There is a 5 x 4.1 x 3.1 cm soft yellow well-circumscribed mass in 1 pole of the kidney. The tumor extends to the renal capsule in multiple areas, but is not seen to penetrate the capsule. In some areas, the tumor is separated by white-tan fibrous septae. In the areas of the kidney uninvolved by tumor, there is a well-defined corticomedullary junction. The cortex measures up to 0.8 cm in thickness, and consists of tan-brown parenchyma. The renal pyramids are well-preserved and consist of pink-tan parenchyma. No lymph nodes or adrenal gland is identified in the perinephric fat. A portion of the tumor is submitted in [REDACTED] for chromosome studies. Intraoperative frozen examination is performed by [REDACTED] Diagnosis by gross examination, right kidney – "Tumor identified 5 cm. Submitted for genome study."

SLIDE KEY

(A1) – Vascular and pelvis/calices margins

(A2) – (A6) – Renal tumor

(A7) – Uninvolved renal parenchyma

MICROSCOPIC DESCRIPTION

The tumor within the right kidney is a clear cell renal cell carcinoma. The tumor grows as rounded nests and occasional solid sheets surrounded by an extensive vascular network. The tumor cells contain abundant amounts of clear to lightly eosinophilic cytoplasm. The nuclei are generally small, round, and

[page 2 of 2]
[REDACTED]

uniform with only minimal pleomorphism and no nucleoli. The tumor is confined to the kidney and does not penetrate the renal capsule. The non-neoplastic kidney is histologically unremarkable. The renal artery, renal vein, and ureter are each negative for tumor.

SURGICAL PATHOLOGY CANCER CASE SUMMARY, KIDNEY

SPECIMEN TYPE: Right radical nephrectomy.

TUMOR SIZE: 5 x 4.1 x 3.1 cm.

HISTOLOGIC TYPE: Conventional (clear cell) renal cell carcinoma.

HISTOLOGIC GRADE: Grade 1.

EXTENT OF INVASION: T1.

MARGINS: Margins uninvolved by tumor.

BLOOD/LYMPHATIC VESSEL INVASION: Absent.

REGIONAL LYMPH NODES: NX.

DISTANT METASTASIS: MX.

[REDACTED]

FINAL DIAGNOSIS

KIDNEY, RIGHT, NEPHRECTOMY

- Conventional (clear cell) renal cell carcinoma, 5 cm.
- Surgical margins negative.
- Please see synoptic report above.

CPT CODE(S): 88307, 88329

[REDACTED]

Source: NCI Genomic Data Commons file 458dc4a1-5b6a-4b2f-928c-348a989ce84e (TCGA-EU-5904.CA3C6E67-3675-42D8-91A1-60FB8AA8CDCD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).